Somatic mutation profile of tumor specimen 0DUME8 from CCDI case PBCLNB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 17.7 years (6,476 days).
Specimen 0DUME8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a65f6471-5f2b-485e-9fca-890ec48d3508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe8699d7-b5f6-48a6-a447-28f7d8e4d5bf

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 180/826 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DDX25 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 28/805 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- FOLH1 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 38/978 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM11 | c.544T>G p.C182G | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
